Somatic mutation profile of tumor specimen TCGA-YR-A95A-01A (aliquot TCGA-YR-A95A-01A-12D-A417-09) from TCGA case TCGA-YR-A95A, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 52.8 years (19,292 days).
Specimen TCGA-YR-A95A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fab40882-c092-46d3-b692-44bf085fc90a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YR-A95A-10A (Blood Derived Normal), aliquot TCGA-YR-A95A-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19331a61-ce44-4735-9c57-08b3c388fd79

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 17, Silent 9, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DLG5 | c.3848C>T p.P1283L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1282713034, COSV64947568; called by muse, mutect2, varscan2
- IRAG1 | c.2675C>T p.S892L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1048108893, COSV70212688; called by muse, mutect2, varscan2
- MEDAG | c.375del p.D126Tfs*12 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs1418142218, COSV66849992; called by pindel, varscan2
- MPPED1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.078); catalogued as COSV68837716; called by muse, mutect2, varscan2
- NLRP5 | c.2722G>T p.D908Y | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199886442; called by muse, mutect2, varscan2
- ZNF500 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1280452143; called by muse, mutect2, varscan2
- APOA4 | c.1181T>G p.L394W | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ARID1A | c.4710dup p.N1571* | Frame Shift Ins (INS) | VAF 13/28 reads (46%) | called by mutect2, pindel, varscan2
- ATP5MC2 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- BMP15 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYSLTR1 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DNAJB8 | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2
- EPC1 | c.990T>A p.D330E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- EPHA2 | c.433dup p.I145Nfs*5 | Frame Shift Ins (INS) | VAF 12/17 reads (71%) | called by mutect2, varscan2
- H3C8 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNIP2 | c.670G>A p.A224T (on ENST00000356640 / NM_173191.3; = p.A239T on NM_014591.5) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PJA1 | c.235T>C p.W79R | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF103 | c.1603A>G p.T535A | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMC4 | c.1816C>G p.L606V (on ENST00000617472 / NM_001145303.3; = p.L600V on NM_144686.4) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM9 | c.87G>T p.A29= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, varscan2
- DMXL2 | c.7029G>A p.L2343= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- ESYT1 | c.612A>G p.K204= | Silent (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- GBP4 | c.1863T>A p.T621= | Silent (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- KCNK13 | c.579C>T p.S193= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs751935222; called by muse, mutect2, varscan2
- RP1 | c.5733T>C p.Y1911= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs770635823; called by muse, mutect2, varscan2
- SOCS4 | c.921C>T p.T307= | Silent (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- TCF7L2 | c.678C>A p.P226= (on ENST00000355995 / NM_001367943.1; = p.P203= on NM_030756.5) | Silent (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.1308C>T p.G436= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs1234966453; called by muse, mutect2, varscan2
